Somatic mutation profile of tumor specimen TARGET-40-NAAEDH-08A (aliquot TARGET-40-NAAEDH-08A-01D) from TARGET case TARGET-40-NAAEDH, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 17.8 years (6,492 days).
Specimen TARGET-40-NAAEDH-08A: Sample type: Post neo-adjuvant therapy; Tissue type: Tumor.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8447cbd5-1c66-4228-ae0b-7be2a3ed1615.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAEDH-10A (Blood Derived Normal), aliquot TARGET-40-NAAEDH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e6b0a6d-15e7-45d4-8703-11568d0fa90b

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLCN5 | c.1003C>A p.L335M | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- FAM171A1 | c.1371C>G p.Y457* | Nonsense Mutation (SNP) | VAF 13/185 reads (7%) | called by muse, mutect2
- LTBP2 | c.931T>C p.S311P | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.046); called by mutect2, varscan2
- PRDM15 | c.582C>G p.H194Q | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2
